Somatic mutation profile of tumor specimen TCGA-AB-2864-03D (aliquot TCGA-AB-2864-03D-01W-0755-09) from TCGA case TCGA-AB-2864, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.0 years (19,724 days).
Specimen TCGA-AB-2864-03D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9106c2e2-c77b-41af-be3b-a88e6eb44574.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2864-11D (Solid Tissue Normal), aliquot TCGA-AB-2864-11D-01W-0755-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/662410c9-4512-49dd-b054-ec776d18d10f

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Frame Shift Ins 2, Silent 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.176C>A p.A59E | Missense Mutation (SNP) | VAF 25/51 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55568979, COSV55604554, COSV55904854; called by muse, mutect2, varscan2
- ASB4 | c.187+2T>G p.X63_splice | Splice Site (SNP) | VAF 43/86 reads (50%) | catalogued as COSV57507461; called by muse, mutect2, varscan2
- ASXL1 | c.2757_2760dup p.S921Tfs*4 | Frame Shift Ins (INS) | VAF 42/131 reads (32%) | catalogued as CI127605; called by mutect2, varscan2
- ATP13A5 | c.2471C>G p.A824G | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60866769; called by muse, mutect2, varscan2
- C6orf118 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs1407950572, COSV57813208; called by muse, mutect2, varscan2
- PPP2R2B | c.1111C>T p.R371C (on ENST00000394409; = p.R437C on NM_181674.2) | Missense Mutation (SNP) | VAF 83/210 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs370195005; called by muse, mutect2, varscan2
- CASZ1 | c.1573G>A p.G525S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC6A9 | c.844A>T p.N282Y (on ENST00000360584 / NM_201649.4; = p.N228Y on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZNF318 | c.4368dup p.V1457Rfs*38 | Frame Shift Ins (INS) | VAF 5/51 reads (10%) | called by pindel, varscan2
- PCDHA13 | c.2193G>A p.A731= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV56482171, COSV99166516; called by muse, varscan2
- ANKRD33 | c.665-57C>T | Intron (SNP) | VAF 32/63 reads (51%) | called by muse, mutect2, varscan2
